Somatic mutation profile of tumor specimen TCGA-61-2008-01A (aliquot TCGA-61-2008-01A-02W-0722-08) from TCGA case TCGA-61-2008, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G2; Age at diagnosis: 40.5 years (14,791 days).
Specimen TCGA-61-2008-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 764b011f-a6ff-4548-8315-47576f2495be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2008-11A (Solid Tissue Normal), aliquot TCGA-61-2008-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a10bca4-2ae5-46f3-aec7-5076d1024828

The open-access MAF lists 80 somatic variants for this specimen: 60 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 17, Splice Site 4, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 2, RNA 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101201456, COSV101202614; called by muse, mutect2, varscan2
- ATP12A | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54513888; called by muse, mutect2, varscan2
- BBS7 | c.852G>C p.M284I | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52655293; called by muse, mutect2, varscan2
- BDH1 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 56/570 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as COSV64018053; called by muse, mutect2
- BLM | c.3835A>G p.I1279V | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV61922704; called by muse, mutect2, varscan2
- BPTF | c.4128G>T p.K1376N | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV58833842; called by muse, mutect2, varscan2
- CCNL2 | c.691G>T p.V231F | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101275726, COSV68766804; called by muse, mutect2, varscan2
- CFAP97 | c.197A>T p.E66V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV99703548; called by muse, mutect2
- CNTNAP2 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs374920791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL15A1 | c.3797G>T p.R1266M | Missense Mutation (SNP) | VAF 87/564 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66642358; called by muse, mutect2, varscan2
- DHX34 | c.155A>T p.Q52L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV60894750; called by muse, mutect2, varscan2
- DOP1A | c.6423T>A p.H2141Q | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52708229, COSV99383096; called by muse, mutect2, varscan2
- EPHB1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 118/620 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781004053, COSV67656570, COSV67657295; called by muse, mutect2, varscan2
- EPOR | c.1397C>T p.T466I | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.235); catalogued as COSV55799900; called by muse, mutect2, varscan2
- ERCC6 | c.423-1G>T p.X141_splice | Splice Site (SNP) | VAF 14/97 reads (14%) | catalogued as COSV63388685; called by muse, mutect2, varscan2
- FGD4 | c.1546C>A p.L516I | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as COSV99847552; called by muse, mutect2
- FRG1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs763602694, COSV56994913; called by mutect2, varscan2
- GIMAP4 | c.15C>G p.Y5* | Nonsense Mutation (SNP) | VAF 64/202 reads (32%) | catalogued as COSV55432243, COSV99751088; called by muse, varscan2
- GOLGA5 | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs762744806, COSV50832375, COSV50833529; called by muse, mutect2, varscan2
- GPRIN3 | c.1180A>G p.I394V | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as rs762242977, COSV60884448; called by muse, mutect2, varscan2
- HGF | c.987G>A p.W329* | Nonsense Mutation (SNP) | VAF 31/140 reads (22%) | catalogued as COSV55946822; called by muse, mutect2, varscan2
- ICAM2 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV56743182; called by muse, mutect2, varscan2
- IGKV1-9 | c.200A>T p.K67M | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.574); catalogued as rs559396862; called by muse, mutect2, varscan2
- IRX6 | c.527A>T p.K176M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51859648; called by muse, mutect2, varscan2
- ITGAL | c.1529T>C p.L510P | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63320894; called by muse, mutect2, varscan2
- KANK4 | c.1238T>A p.M413K | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV62985881; called by muse, mutect2, varscan2
- KIF21B | c.1119G>C p.K373N | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV100144941, COSV59754490; called by muse, mutect2, varscan2
- LONRF1 | c.2311C>A p.Q771K | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as COSV68036256; called by muse, mutect2, varscan2
- MARS2 | c.891C>G p.F297L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV56570945; called by muse, mutect2, varscan2
- NNT | c.2175A>T p.E725D | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.026); catalogued as COSV104391081, COSV52923695; called by muse, mutect2, varscan2
- OGT | c.1361C>A p.T454K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.796); catalogued as rs1204659204, COSV65480067; called by muse, mutect2, varscan2
- OR10J3 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 180/363 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV59953893; called by muse, mutect2, varscan2
- OS9 | c.1258G>C p.D420H | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV57782277, COSV57782574; called by muse, mutect2, varscan2
- PCNX1 | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.185); catalogued as COSV99457017; called by muse, mutect2, varscan2
- PIWIL3 | c.869G>C p.R290P | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59994067, COSV59994372; called by muse, mutect2, varscan2
- PLXNB1 | c.2656A>G p.I886V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.133); catalogued as rs1303499797, COSV56487919; called by muse, mutect2
- PRRC2B | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61935170; called by muse, mutect2, varscan2
- RBM15 | c.1688G>C p.G563A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV63923260, COSV63923490; called by muse, mutect2, varscan2
- RIF1 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV54614499; called by muse, mutect2, varscan2
- SCLY | c.1030-2A>C p.X344_splice (on ENST00000651534; = p.X336_splice on NM_016510.7) | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV54540653; called by muse, mutect2, varscan2
- SF3B1 | c.481T>A p.L161M | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV100135617; called by muse, mutect2, varscan2
- SPTA1 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 110/485 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV100935485, COSV63751842; called by muse, mutect2, varscan2
- SYNE1 | c.20078A>G p.H6693R (on ENST00000367255 / NM_182961.4; = p.H6622R on NM_033071.3) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1415636574, COSV54935542; called by muse, mutect2, varscan2
- TEKT5 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs201676909; called by muse, mutect2, varscan2
- TNFSF10 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99577900; called by muse, mutect2, varscan2
- TOGARAM2 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65420428; called by muse, mutect2, varscan2
- TOPORS | c.554C>A p.T185K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV62116469; called by muse, mutect2, varscan2
- TP53 | c.351dup p.T118Dfs*31 | Frame Shift Ins (INS) | VAF 128/235 reads (54%) | catalogued as COSV53352302, COSV53449281; called by mutect2, pindel, varscan2
- TTN | c.66086del p.G22029Efs*22 (on ENST00000591111; = p.G14605Efs*22 on NM_003319.4) | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as COSV60355261; called by mutect2, varscan2
- UGT1A9 | c.395A>T p.K132I | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV60834294, COSV60834786; called by muse, mutect2, varscan2
- UNC79 | c.6070G>C p.G2024R (on ENST00000393151 / NM_001346218.2; = p.G1847R on NM_020818.5) | Missense Mutation (SNP) | VAF 117/198 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV56374727, COSV56379542; called by muse, mutect2, varscan2
- ZFP64 | c.1655dup p.Q553Sfs*61 | Frame Shift Ins (INS) | VAF 12/115 reads (10%) | catalogued as rs760917371; called by mutect2, varscan2
- ZNF652 | c.648T>A p.S216R | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV62946472; called by muse, varscan2
- ZNF76 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 135/663 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764649836, COSV99987809; called by muse, mutect2, varscan2
- BCKDHB | c.708del p.F238Lfs*16 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- COBL | c.784-2_804del p.X262_splice | Splice Site (DEL) | VAF 8/40 reads (20%) | called by mutect2, varscan2
- NBPF9 | c.121A>G p.R41G | Missense Mutation (SNP) | VAF 54/376 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PPFIBP2 | c.1279_1294del p.G427Pfs*25 | Frame Shift Del (DEL) | VAF 56/320 reads (18%) | called by mutect2, pindel, varscan2
- RAB3GAP2 | c.1041-29_1062del p.X347_splice | Splice Site (DEL) | VAF 42/376 reads (11%) | called by mutect2, pindel
- SLC5A6 | c.340_349del p.A114Sfs*31 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- ABCF3 | c.999G>A p.R333= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs755572921, COSV53054603; called by muse, mutect2
- ATRNL1 | c.1809C>T p.L603= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs267602377, COSV61800040; called by muse, mutect2, varscan2
- CLUL1 | c.1302C>G p.L434= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs1360413699, COSV58111599; called by muse, mutect2, varscan2
- CT45A1 | c.150T>G p.S50= | Silent (SNP) | VAF 216/6598 reads (3%) | called by muse, mutect2
- CUL2 | c.1572A>G p.S524= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV66078672; called by muse, mutect2, varscan2
- DICER1 | c.3705T>C p.C1235= | Silent (SNP) | VAF 34/163 reads (21%) | catalogued as COSV100602498; called by muse, mutect2, varscan2
- FLG2 | c.381A>T p.S127= | Silent (SNP) | VAF 54/288 reads (19%) | catalogued as COSV101166158; called by muse, mutect2, varscan2
- GFOD2 | c.21G>T p.V7= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV52057373; called by muse, mutect2, varscan2
- GTF2H4 | c.1029G>T p.V343= | Silent (SNP) | VAF 30/179 reads (17%) | catalogued as COSV52558211; called by muse, mutect2, varscan2
- INSR | c.2361C>T p.S787= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs751613599, COSV57159721; ClinVar: likely benign; called by muse, mutect2
- IQCH | c.2898C>T p.T966= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV60050749; called by muse, mutect2, varscan2
- MCOLN2 | c.1389T>C p.D463= | Silent (SNP) | VAF 36/242 reads (15%) | catalogued as COSV52294150; called by muse, mutect2, varscan2
- MYBBP1A | c.3678G>A p.G1226= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV54595480; called by muse, mutect2, varscan2
- SEC24B | c.1533G>A p.L511= | Silent (SNP) | VAF 55/115 reads (48%) | catalogued as COSV54496869; called by muse, mutect2, varscan2
- SMS | c.501T>C p.D167= | Silent (SNP) | VAF 27/281 reads (10%) | catalogued as rs1244188661, COSV65113854; called by muse, mutect2
- TOR1AIP2 | c.414C>G p.A138= | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as COSV62625782; called by muse, mutect2, varscan2
- ZNF589 | c.25C>T p.L9= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV100685803; called by muse, mutect2, varscan2
- FCN1 | c.-1C>A | 5'UTR (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100878963; called by muse, mutect2, varscan2
- MDS2 | n.795A>T | RNA (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.521-3630G>A | Intron (SNP) | VAF 276/780 reads (35%) | catalogued as rs774180774, COSV101115152; called by muse, mutect2, varscan2
